OHSU case 1946 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4346445e-f278-4674-b6a0-b7e6db43a5ee

Demographics
Sex at birth: male.

Diagnoses (1)
1. Chronic neutrophilic leukemia: ICD-O-3 morphology code: 9963/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,932 days); Days to last follow up: 320 days.

Biospecimens (1 sample)
- Sample 4654D: Tissue type: Tumor; Preservation method: Snap Frozen.
